Gene-level copy-number profile of tumor specimen TCGA-EJ-7794-01A from TCGA case TCGA-EJ-7794, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.0 years (24,478 days).
Specimen TCGA-EJ-7794-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.cda5c305-a85e-4da1-9b00-e7803bca2053.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7794-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2fc0bf2b-0c02-40e2-82aa-2144534d7fde

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 5,341; copy number 2: 54,460.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7794-01A-11D-2112-01): tumor purity 0.34, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:112,142,441–112,419,313, 1 gene (within-gene range 0–1): EPB41L4A.
- chr5:112,228,283–112,867,582, 10 genes (within-gene range 0–1): AC104126.1, AC010265.1, EPB41L4A-DT, HMGB3P16, AC137549.1, LINC02200, APC, CBX3P3, RNU6-482P, AC008575.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,962. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
